Gene-level copy-number profile of tumor specimen TCGA-B9-A5W9-01A from TCGA case TCGA-B9-A5W9, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 40.2 years (14,668 days).
Specimen TCGA-B9-A5W9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRP.c1e150da-77d6-4d00-bd15-9d263a0d1474.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B9-A5W9-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/44f8ccb5-9b12-4164-80ad-8fd879f68e01

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,643; copy number 2: 39,149; copy number 3: 10,718; copy number 4: 7,167; copy number 5: 137.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B9-A5W9-01A-11D-A28F-01): tumor purity 0.88, ploidy 2.42, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 137 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:27,406,530–28,809,291, 7 genes, copy number 5: AC113355.1, AC093300.1, LINC02103, AC008825.1, AC109472.1, RNU6-909P, AC008825.2.
- chr5:28,897,785–28,927,459, 4 genes, copy number 5: AC010385.2, LSP1P3, AC010385.1, AC010385.3.
- chr5:38,682,581–39,572,639, 13 genes, copy number 5 (within-gene range 3–5): OSMR-AS1, AC091435.1, AC091435.2, OSMR, RICTOR, AIG1P1, AC008964.1, FYB1, GOLGA5P1, C9, DAB2, LINC02104, CCDC11P1.
- chr5:44,300,247–44,658,569, 3 genes, copy number 5 (within-gene range 3–5): FGF10, FGF10-AS1, LINC02224.
- chr8:150,584–6,648,508, 86 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:6,622,124–6,622,220, 1 gene, copy number 5: MIR8055.
- chr17:69,961,568–72,220,948, 21 genes, copy number 5 (within-gene range 4–5): LINC01497, Y_RNA, AC005208.1, LINC01028, KCNJ16, KCNJ2-AS1, KCNJ2, CALM2P1, AC011990.1, AC005771.1, AC007423.1, AC005181.1, CASC17, RNU7-155P, AC118653.1, MYL6P5, AC007432.1, AC005144.1, ROCR, LINC01152, AC007461.1.
- chr17:72,072,333–72,126,416, 2 genes, copy number 5: LINC02097, SOX9.

Autosomal genes at a single copy (total copy number 1): 222. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
